Surgical pathology report (de-identified scan), TCGA case TCGA-BD-A3ER, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BD-A3ER-01A (Primary Tumor).

[page 1 of 3]
FINAL DIAGNOSIS:

PART 1: LIVER, RIGHT LOBE #2, RANDOM BIOPSY

- SEVERE MIXED MICRO-AND MACROVESICULAR STEATOSIS INVOLVING 70% OF THE LIVER PARENCHYMA AND MILD SEPTAL CHRONIC INFLAMMATION.
- ESTABLISHED CIRRHOSIS.
- THERE IS NO EVIDENCE OF MALIGNANCY.

PART 2: LIVER, RIGHT LOBE #3, RANDOM NEEDLE BIOPSY

- SEVERE MIXED MICRO-AND MACROVESICULAR STEATOSIS INVOLVING APPROXIMATELY 70% OF THE LIVER PARENCHYMA AND MILD SEPTAL CHRONIC INFLAMMATION.
- ESTABLISHED CIRRHOSIS.
- THERE IS NO EVIDENCE OF MALIGNANCY.

PART 3: LIVER, RIGHT LOBE TUMOR, SEGMENT 8, NEEDLE BIOPSY

- HEPATOCELLULAR CARCINOMA, MODERATELY DIFFERENTIATED (SEE COMMENT).
- BACKGROUND LIVER WITH SEVERE MIXED MICRO-AND MACROVESICULAR STEATOSIS INVOLVING APPROXIMATELY 70% OF THE LIVER PARENCHYMA AND ESTABLISHED CIRRHOSIS.

PART 4: LIVER, SEGMENT 8, SEGMENTECTOMY (52 GRAMS)

- STEATOTIC HEPATOCELLULAR CARCINOMA, MODERATELY DIFFERENTIATED.
SIZE = 2.7 X 2.4 X 2.0 CM.
- MARGINS = 0.4 CM FROM THE CLOSEST PARENCHYMAL RESECTION MARGIN.
- ALCOHOL STAGE: PT2, NX, NX.
- BACKGROUND LIVER WITH SEVERE MIXED MICRO-AND MACROVESICULAR STEATOSIS INVOLVING APPROXIMATELY 70% OF THE LIVER PARENCHYMA AND ESTABLISHED CIRRHOSIS.

PART 5: LIVER, SEGMENT 4B, WEDGE RESECTION (4 GRAMS)

- SUBCAPSULAR WEDGE OF HEPATIC TISSUE WITH FOREIGN BODY GIANT CELL REACTION TO NECROTIC FOCI (SEE COMMENT).
- THERE IS NO EVIDENCE OF VIABLE TUMOR CELLS.
- BACKGROUND LIVER WITH SEVERE MIXED MICRO-AND MACROVESICULAR STEATOSIS INVOLVING 70% OF THE LIVER PARENCHYMA AND ESTABLISHED CIRRHOSIS.

PART 6: GALLBLADDER, CHOLECYSTECTOMY

- CHRONIC CHOLECYSTITIS.
- THERE IS NO EVIDENCE OF MALIGNANCY.

DME/DMS COMMENT:

Surgeon Dr. [redacted] was informed that no specimen was found in container labeled, "Random biopsy, right lobe #1." Parts 1 and 2: Liver, right lobe, #2 and #3, random needle biopsies: Histologic examination of the multiple needle core biopsies of hepatic tissue reveal severe mixed microvesicular and macrovesicular steatosis involving 70% of the hepatic parenchyma with established cirrhosis. There is no evidence of malignancy as confirmed using immunohistochemical and special stains. There is loss of reticulin framework in steatotic areas, but this is seen in benign fatty liver. Immunohistochemical stain to Glypican 3 is negative. CD34 failed to show sinusoidal capillarization. Ki67 shows no significant increase in proliferation rate. According to the electronic medical records, the patient is heterozygous for hemochromatosis. No confirmatory molecular studies for hemochromatosis gene (HFE) mutation were seen in the medical records and no increased hepatocyte iron deposits were seen using the iron stain. Clinical correlation is suggested.

Overall, the histopathological changes of background liver are most consistent with an active steatohepatitis, although other causes of liver injury should be clinically and serologically excluded. Steatohepatitis is a non-specific pattern of injury seen most commonly with morbid obesity, diabetes, insulin resistance, and alcohol abuse. However, it can also be associated with nutritional causes, such as protein-calorie malnutrition, starvation, rapid weight loss, and various intestinal bypass or gastric stapling surgeries. Hepatic steatosis and steatohepatitis can also be the result of medications, including amiodarone, perhexiline maleate, glucocorticoids, synthetic estrogens, calcium channel blockers, tamoxifen, methotrexate, valproic acid, cocaine, and anti-viral agents (Zidovudine, Didanosine, and Fialuridine). Metabolic disorders can also cause steatosis and steatohepatitis: hyperlipidemia, Wilson's disease, adult onset citrullinemia (type 1), lipodystrophy, dysbetalipoproteinemia, Weber-Christian disease, Wolman's disease, Cholesterol ester storage disease, and fatty liver of pregnancy. Other causes include inflammatory bowel disease, intestinal bacterial overgrowth, and exposure to environmental toxins, including phosphorus, petrochemicals, toxic mushrooms, and organic solvents. Hepatic blood flow abnormalities can also cause hepatic steatosis and steatohepatitis. Examples include pre-hepatic portal hypertension, porto-systemic shunting, and patent ductus venosus.

Part 3: Liver, right lobe tumor, segment 8, needle biopsy: The specimen consists of two cores of hepatic tissue. One of which is steatotic cirrhotic liver, similar to that seen in parts 1-2 of the right lobe needle biopsies. The other core of tissue is composed of eosinophilic cells arranged in acini and trabeculae with increased nuclear to cytoplasmic ratio. There is necrosis involving 1st of this core and there is a focus of stromal invasion. Immunohistochemical stain to CD34 shows sinusoidal capillarization. Glypican 3 weakly stains the cells. Ki67 shows a slight increase in proliferation rate. No loss of the reticulin framework is seen. Taken together these results support the diagnosis of well differentiated hepatocellular carcinoma.

Part 4: Liver, right lobe tumor, segment 8, segmentectomy: This histologic features of the steatotic hepatocellular carcinoma are similar to previous biopsy

steatotic hepatocellular carcinoma is difficult. The diagnosis is supported by immunohistochemical stains include Ki67, glutamine synthetase, smooth muscle actin and CD34. CD34 shows capillarization of the sinusoids. Ki67 shows a slight increased rate of proliferation in comparison to the cirrhotic background liver. Aberrant arteries are seen using smooth muscle actin. Diffuse CRP and glutamine synthetase staining is seen. Loss of the reticulin framework is seen. pSTAT3 only stains rare nuclei. No nuclear beta catenin staining is seen. AFP and glypican3 are negative. Taken together these results support the diagnosis of hepatocellular carcinoma. Loss of heterozygosity studies are pending and these results will be reported in an addendum.

Part 5: Liver, left lobe, segment 4B, wedge resection: The specimen consists of a wedge resection with a capsular foreign body giant cell reaction to necrotic material. No viable tumor cells are seen. None to equivocal yeast forms are seen on . No organisms are seen using gram and AFB stain. The differential diagnoses include infarcted tumor foci, infections, such as histoplasmosis, old subcapsular hematoma, etc. Clinical correlation required.

1CB-0-3

carcinoma, hepatocellular, NOS

8170/3

Site: liver c22.0

on 11/4/11

[page 2 of 3]
SYNOPTIC DATA - PRIMARY LIVER HEPATOCELLULAR CARCINOMA TUMORS

SPECIMEN TYPE: Other: Right lobe segment 8

FOCALITY: Multiple: Segment 8 (2 lesions: one was resected and other one was ablated).

TUMOR SIZE: Greatest dimension: 2.7 cm
Additional dimensions: 2.4x2.0 cm

HISTOLOGIC TYPE: Hepatocellular carcinoma

HISTOLOGIC GRADE: GII: Moderately differentiated

MACROSCOPIC VENOUS (LARGE VESSEL) INVASION (V): Not identified

MICROSCOPIC (SMALL VESSEL) INVASION (L): Not identified

LIVER-PERINEURAL INVASION: Not identified

TNM DESCRIPTORS: m

PATHOLOGIC STAGING (pTNM): pT2

PNX
Number of regional lymph nodes examined: 0
Number of nodes regional lymph involved: 0
PMO

MARGINS: Parenchymal Margin uninvolved by invasive carcinoma
Parenchymal Margin: Distance of invasive carcinoma from closest margin: 0.4 mm

ADDITIONAL PATHOLOGIC FINDINGS: Cirrhosis/advanced fibrosis
Other: steatohepatitis

PATIENT HISTORY:

year-old man with history of history of heterozygous hemochromatosis along with prostate CA that was diagnosed in . Now with enlarging hypervascular liver mass. Liver biopsy confirms hepatocellular carcinoma. The patient denies any history of viral hepatitis. He has moderate social drinking but quit . Denies any history of GI bleed, hepatic encephalopathy, ascites, or jaundice. Imaging shows a solitary 2.5 cm hypervascular mass in the right lobe of the liver. Quantitative testing for hepatitis C virus is negative at <25 iu/ml. Quantitative testing for hepatitis B virus infection gave a viral titer of <300 iu/ml. CT of the abdomen on 11 showed 3 segment 8 and 1 segment 5 hypervascular hepatic lesions with persistent portal venous enhancement. Background liver shows cirrhotic morphology. Liver function tests on AST 55, ALT 48, GGTP 138, total bilirubin 0.7, hepatitis C virus antibody negative at 0.09, alpha-fetoprotein negative at 5.

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Liver lesion biopsy, proven hepatocellular carcinoma, PMH hemochromatosis, prostate cancer.

PROCEDURE: Partial right hepatic lobectomy segment 8 tumor, resection of left lobe segment 4B lesion, open radiofrequency ablation of the left lobe tumor of the right lobe x 3, ultrasound guidance for monitoring of tissue ablation, needle liver biopsy, open cholecystectomy and intraoperative cholangiogram.

[page 3 of 3]
ADDENDA:

Addendum

Molecular Anatomic Pathology Testing:

Block 3A, microdissection target 1 (T1):

A. Loss of heterozygosity is IDENTIFIED at chromosome 5q (37%).

B. Fractional Allelic Loss is 8% (1 locus with loss/12 informative loci).

Block 4B, microdissection target 2 (T2):

A. Loss of heterozygosity is IDENTIFIED at chromosome 1p (32%).

B. Fractional Allelic Loss is 8% (1 locus with loss/12 informative loci).

Note:

LOH of high amplitude is considered when more than 75% of cellular DNA is affected.

Loss of heterozygosity of tumor suppressor gene alleles is known to occur in liver neoplasias and to correlate with tumor progression. As reported in the literature, benign neoplasms (hepatic adenoma and focal nodular hyperplasia) typically have low frequency of LOH (mean fractional allelic loss ~6%) and hepatocellular carcinomas (HCC) frequently have higher prevalence of LOH (mean fractional allele loss ~30%) (1,2). Some studies have shown that HCC with FAL of <30% are associated with indolent biological behavior and FAL of >30% with an aggressive biological behavior (3-5). LOH mutations are reported as high amplitude when more than 75% of cellular DNA is affected. Some HCC with low amplitude LOH mutations and FAL 25-35% considered to be indeterminate biological behavior. However, not all tumors reveal such a correlation and, therefore, the LOH profile should be interpreted in the context of the cytologic and histologic findings and the patient's clinical history.

Sample Preparation and LOH Analysis

Manual microdissection of the tissue sample was performed to include tumor tissue and normal adjacent tissue (if available) or a blood sample. DNA was isolated using standard laboratory procedure. Specimens with the minimum of 50% of tumor cells in a microdissection target are accepted for the analysis. Optical density readings were obtained.

Eighteen microsatellite markers (listed below) that have been previously found to be involved in liver neoplasia and/or co-localize with known tumor suppressor genes were used for analysis. PCR was performed using

fluorescently labeled primers and the products of amplification were detected using capillary electrophoresis on ABI3730 platform. Relative fluorescence was determined for individual alleles and the ratio of peaks was calculated.

Normal tissue was examined to determine whether the patient is heterozygous at the marker (genetically informative) and neoplastic tissue was then analyzed to detect loss of heterozygosity. Thresholds for significant allelic imbalance were determined using normal (non-neoplastic) specimens for every marker. Loss of heterozygosity was determined using (NL / NS) / (TL/TS) formula and reported when allelic ratio for a particular marker was below 0.5 or above 2.0. When normal tissue was not available, peak height ratios falling outside of 2 SDs beyond the mean for each polymorphic allele pairing were assessed as showing loss of heterozygosity.

D1S407 1p36 CMM/RIZ

D1S171 1p36 CMM/RIZ

D3S1539 3p26 VHL/OGG1

D3S516 3p26 VHL/OGG1

D5S1384 5q23 APC

D5S615 5q23 APC

D8S254 8p22 ---

D8S261 8p22 ---

D9S251 9p21 CDKN2A

D9S1748 9p23 CDKN2A

D10S520 10q23 PTEN

D10S1173 10q23 PTEN

D17S974 17p13 TP53

D17S1249 17p13 TP53

D17S1877 17q23 Her2/neu

D18S487 18q21 DCC

D21S1256 21q22 ETS2

D22S268 22q13 NF2

1. Chen YJ, et al. Chromosomal analysis of hepatic adenoma and focal nodular hyperplasia by comparative genomic hybridization. *Genes Chromosomes Cancer*. 2002 Oct;35(2):138-43.

2. Cha C, Dematteo RP. Molecular mechanisms in hepatocellular carcinoma development. *Best Pract Res Clin Gastroenterol*. 2005 Feb;19(1):25-37.

3. Finkelstein SD, et al. Microdissection-based allelotyping discriminates de novo tumor from intrahepatic spread in hepatocellular carcinoma. *Hepatology*. 2003 Apr;37(4):871-9.

4. Marsh JW, et al. Genotyping of hepatocellular carcinoma in liver transplant recipients adds predictive power for determining recurrence-free survival. *Liver Transpl*. 2003 Jul;9(7):664-7.

5. Morimoto O, et al. Diagnosis of intrahepatic metastasis and multicentric carcinogenesis by microsatellite loss of heterozygosity in patients with multiple and recurrent hepatocellular carcinomas. *J. Hepatol*. 2003 Aug;39(2):215-21.

	Yes	No
Reflex		

Source: NCI Genomic Data Commons file e6f6b38f-3a07-467e-bccb-c122bac59d59 (TCGA-BD-A3ER.2CD158D7-48E7-43D6-8E0F-2D56FC6F5256.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).